Somatic mutation profile of tumor specimen C3L-01286-03 (aliquot CPT0086960009) from CPTAC case C3L-01286, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 58.7 years (21,429 days).
Specimen C3L-01286-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70b8804e-f8ac-4330-a3ea-1f5a866b3e43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01286-31 (Blood Derived Normal), aliquot CPT0087450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/090f95e7-a711-411d-ae52-d717020301ea

The open-access MAF lists 108 somatic variants for this specimen: 77 protein-altering or splice-affecting, 17 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 17, Intron 5, 3'UTR 4, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 3, Splice Site 3, 5'Flank 3, Splice Region 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 121/483 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs750194005, COSV66583891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD24 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs758342016; called by muse, varscan2
- CCDC42 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 143/600 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs781345210; called by muse, mutect2, varscan2
- CDH22 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 96/565 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.855); catalogued as rs926295661; called by muse, mutect2, varscan2
- CEP295 | c.3763G>C p.D1255H | Missense Mutation (SNP) | VAF 62/308 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV57349476; called by muse, mutect2, varscan2
- CPLX2 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 152/792 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1334772726; called by muse, mutect2, varscan2
- DAAM1 | c.2164G>T p.D722Y | Missense Mutation (SNP) | VAF 99/412 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1419113038; called by muse, mutect2, varscan2
- EIF2B2 | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 468/948 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as CM152520, COSV56720257; called by muse, mutect2, varscan2
- HGFAC | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs577434025, COSV66977323; called by muse, mutect2
- KCNH7 | c.1820G>C p.G607A | Missense Mutation (SNP) | VAF 145/345 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1169469826, COSV59790106; called by muse, mutect2, varscan2
- KIAA0319L | c.393A>T p.L131F | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs41310436, COSV57843171, COSV57844099; called by muse, mutect2, varscan2
- KRT2 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 282/1056 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1330514030; called by muse, mutect2, varscan2
- NOXRED1 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs1337366655; called by muse, mutect2
- OR2L2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 168/749 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as rs753145578, COSV63551776; called by muse, mutect2, varscan2
- OR52N1 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 192/884 reads (22%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.859); catalogued as COSV57693368, COSV57693885; called by muse, mutect2, varscan2
- PAGR1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 203/886 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV56188506; called by muse, mutect2, varscan2
- PATL1 | c.1630C>G p.L544V | Missense Mutation (SNP) | VAF 84/376 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as COSV55693559; called by muse, mutect2, varscan2
- PCNX3 | c.4855C>T p.R1619C | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758077741, COSV63136005; called by muse, mutect2, varscan2
- PCSK5 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 175/514 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406686253, COSV65084371; called by muse, mutect2, varscan2
- QSER1 | c.1886C>T p.S629L (on ENST00000399302; = p.S758L on NM_001076786.3) | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV67899550; called by muse, mutect2, varscan2
- REST | c.1823T>C p.M608T | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1387308478; called by muse, mutect2, varscan2
- SETD2 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 30/89 reads (34%) | catalogued as COSV57434480, COSV57448778; called by muse, mutect2, varscan2
- ST18 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs141556653; called by muse, mutect2, varscan2
- TERT | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 451/1152 reads (39%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1554042981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNRC18 | c.3296T>C p.L1099P | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1174060554; called by muse, mutect2, varscan2
- TTC33 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 101/474 reads (21%) | catalogued as rs374271035; called by muse, mutect2, varscan2
- TTLL10 | c.477C>A p.F159L (on ENST00000379289 / NM_001130045.2; = p.F86L on NM_153254.3) | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV64959736; called by muse, mutect2, varscan2
- ABCA10 | c.4533+2T>A p.X1511_splice | Splice Site (SNP) | VAF 81/408 reads (20%) | called by muse, mutect2, varscan2
- ACAA1 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 270/413 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AKAP6 | c.1944A>C p.E648D | Missense Mutation (SNP) | VAF 135/534 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ANKS1B | c.2261T>A p.V754D | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C16orf89 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN9 | c.402G>A p.Q134= | Splice Region (SNP) | VAF 61/291 reads (21%) | called by muse, mutect2, varscan2
- CARMIL1 | c.3177G>T p.K1059N | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CEP290 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- CYFIP1 | c.2567G>A p.C856Y | Missense Mutation (SNP) | VAF 102/321 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DMD | c.2243C>A p.A748E | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DPCD | c.247_259del p.L83Afs*14 | Frame Shift Del (DEL) | VAF 72/447 reads (16%) | called by pindel, varscan2
- E2F1 | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 114/940 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFCAB5 | c.1275G>C p.R425S | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- EFR3B | c.1654del p.L552Sfs*49 | Frame Shift Del (DEL) | VAF 150/656 reads (23%) | called by mutect2, pindel, varscan2
- EMILIN3 | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 254/581 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EML5 | c.3586G>T p.V1196L | Missense Mutation (SNP) | VAF 117/342 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- FLT1 | c.1184dup p.T396Nfs*2 | Frame Shift Ins (INS) | VAF 118/453 reads (26%) | called by mutect2, pindel, varscan2
- FZD3 | c.1553+2T>G p.X518_splice | Splice Site (SNP) | VAF 124/237 reads (52%) | called by muse, mutect2, varscan2
- HEY1 | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 155/630 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHIPL2 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 669/1126 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IL6ST | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 195/530 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- JUP | c.848_853delinsG p.K283Sfs*37 | Frame Shift Del (DEL) | VAF 102/1079 reads (9%) | called by pindel, varscan2*
- KIAA1614 | c.2105T>A p.F702Y | Missense Mutation (SNP) | VAF 406/692 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- KIAA1841 | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 69/114 reads (61%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF1A | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 88/352 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KISS1 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 738/1275 reads (58%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP1 | c.2344G>A p.E782K (on ENST00000404816 / NM_206943.4; = p.E456K on NM_000627.4) | Missense Mutation (SNP) | VAF 104/481 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MAP3K19 | c.3535G>T p.E1179* | Nonsense Mutation (SNP) | VAF 77/361 reads (21%) | called by muse, mutect2, varscan2
- MGAT3 | c.773C>G p.T258S | Missense Mutation (SNP) | VAF 168/237 reads (71%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NIPAL3 | c.93+7del | Splice Region (DEL) | VAF 89/317 reads (28%) | called by mutect2, pindel, varscan2
- NOP53 | c.1374-2A>T p.X458_splice | Splice Site (SNP) | VAF 180/568 reads (32%) | called by muse, mutect2, varscan2
- NPIPB2 | c.491A>T p.K164I (on ENST00000399147; = p.K24I on NM_001355514.1) | Missense Mutation (SNP) | VAF 224/1072 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR9G4 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 137/537 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PBRM1 | c.4853_4864del p.S1618_S1621del (on ENST00000296302 / NM_001366071.2; = p.S1511_S1514del on NM_018313.5) | In Frame Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- PHF20 | c.2580G>T p.R860S | Missense Mutation (SNP) | VAF 816/1164 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLXNC1 | c.1900T>C p.C634R | Missense Mutation (SNP) | VAF 105/390 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNC1 | c.2116G>T p.D706Y | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PROX2 | c.1760C>T p.S587F (on ENST00000556489 / NM_001243007.1; = p.S360F on NM_001080408.2) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- S100A10 | c.51C>A p.H17Q | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- SEH1L | c.46C>G p.H16D | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SLC17A7 | c.435_440del p.R145_F147delinsS | In Frame Del (DEL) | VAF 181/421 reads (43%) | called by mutect2, pindel, varscan2
- SPACA1 | c.731G>C p.W244S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPARCL1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TRMT5 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 134/519 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPS13B | c.1312A>G p.M438V | Missense Mutation (SNP) | VAF 153/645 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- WDR41 | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR91 | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 192/520 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZBTB3 | c.1024T>A p.S342T | Missense Mutation (SNP) | VAF 87/363 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYM5 | c.1390_1404del p.E464_Q468del | In Frame Del (DEL) | VAF 47/303 reads (16%) | called by mutect2, pindel, varscan2
- ZNF114 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.33); called by muse, mutect2
- ALMS1 | c.1977G>A p.T659= | Silent (SNP) | VAF 86/337 reads (26%) | catalogued as rs201316401; ClinVar: likely benign; called by muse, mutect2, varscan2
- B3GALT1 | c.198T>C p.L66= | Silent (SNP) | VAF 128/252 reads (51%) | called by muse, mutect2, varscan2
- CACNA1H | c.5685C>T p.D1895= | Silent (SNP) | VAF 96/367 reads (26%) | catalogued as rs1463806903, COSV52356542; called by muse, mutect2, varscan2
- CPA5 | c.681G>T p.L227= | Silent (SNP) | VAF 47/324 reads (15%) | catalogued as COSV62568748; called by muse, mutect2, varscan2
- CTAGE15 | c.1257G>A p.V419= | Silent (SNP) | VAF 201/1401 reads (14%) | catalogued as rs1455939379; called by muse, mutect2, varscan2
- GNPTAB | c.2466C>G p.T822= | Silent (SNP) | VAF 61/265 reads (23%) | called by muse, mutect2, varscan2
- GPAT2 | c.1188C>T p.G396= | Silent (SNP) | VAF 282/568 reads (50%) | catalogued as rs746992961; called by muse, mutect2, varscan2
- HCRTR1 | c.999C>T p.R333= | Silent (SNP) | VAF 57/218 reads (26%) | catalogued as rs200222372; called by muse, mutect2, varscan2
- ITIH1 | c.1275G>A p.R425= | Silent (SNP) | VAF 127/230 reads (55%) | called by muse, mutect2, varscan2
- LHX5 | c.33C>T p.P11= | Silent (SNP) | VAF 118/427 reads (28%) | catalogued as rs897376357; called by muse, mutect2, varscan2
- MCM10 | c.1389G>A p.G463= (on ENST00000484800 / NM_182751.3; = p.G462= on NM_018518.5) | Silent (SNP) | VAF 161/487 reads (33%) | called by muse, mutect2, varscan2
- METTL25 | c.1668C>T p.P556= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as COSV50261609; called by muse, mutect2, varscan2
- SLC9A9 | c.1113G>A p.L371= | Silent (SNP) | VAF 90/296 reads (30%) | called by muse, mutect2, varscan2
- VNN2 | c.1287C>T p.F429= | Silent (SNP) | VAF 81/295 reads (27%) | called by muse, mutect2, varscan2
- WDR41 | c.1128C>T p.S376= | Silent (SNP) | VAF 77/267 reads (29%) | called by muse, mutect2, varscan2
- ZBTB46 | c.84C>T p.G28= | Silent (SNP) | VAF 505/700 reads (72%) | catalogued as rs368634130; called by muse, mutect2, varscan2
- ZNF777 | c.1017C>T p.R339= | Silent (SNP) | VAF 113/640 reads (18%) | catalogued as rs373973043; called by muse, mutect2, varscan2
- CRISPLD2 | c.240+31C>A | Intron (SNP) | VAF 178/673 reads (26%) | called by muse, mutect2, varscan2
- DENND2C | c.*18A>G | 3'UTR (SNP) | VAF 39/118 reads (33%) | catalogued as rs201437846; called by muse, mutect2, varscan2
- E2F6 | c.164-1628C>A | Intron (SNP) | VAF 28/105 reads (27%) | called by muse, mutect2, varscan2
- LRR1 | chr14:49598843 C>T | 5'Flank (SNP) | VAF 57/211 reads (27%) | called by muse, mutect2, varscan2
- MIR124-2 | chr8:64378189 G>A | 5'Flank (SNP) | VAF 37/179 reads (21%) | called by muse, mutect2, varscan2
- MMP9 | c.1902-16C>G | Intron (SNP) | VAF 170/1228 reads (14%) | called by muse, mutect2, varscan2
- RAX2 | c.*19C>A | 3'UTR (SNP) | VAF 102/400 reads (26%) | catalogued as rs1391595572; called by muse, mutect2, varscan2
- RECQL4 | c.-41T>C | 5'UTR (SNP) | VAF 36/110 reads (33%) | catalogued as rs1564813478; called by muse, mutect2, varscan2
- SCFD1 | c.613+604C>T | Intron (SNP) | VAF 88/403 reads (22%) | called by muse, mutect2, varscan2
- SNORD114-31 | chr14:100990169 A>G | 5'Flank (SNP) | VAF 52/198 reads (26%) | catalogued as rs745746858; called by muse, mutect2, varscan2
- SOX5 | c.*1010C>A | 3'UTR (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- SPATA7 | c.190+37T>G | Intron (SNP) | VAF 90/331 reads (27%) | called by muse, mutect2, varscan2
- TMEM134 | c.*30_*39del | 3'UTR (DEL) | VAF 114/509 reads (22%) | called by mutect2, pindel, varscan2
- TPM1 | chr15:63069969 G>A | 3'Flank (SNP) | VAF 218/590 reads (37%) | catalogued as rs747553234; called by muse, mutect2, varscan2
